Gene-level copy-number profile of tumor specimen TCGA-IN-A6RL-01A from TCGA case TCGA-IN-A6RL, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 84.3 years (30,783 days).
Specimen TCGA-IN-A6RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.eb37dd13-72a7-480c-8d82-fd97281a2f5d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/794561f7-7ffb-4017-afbb-417f30099441

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 43; copy number 2: 3,838; copy number 3: 15,220; copy number 4: 16,539; copy number 5: 16,571; copy number 6: 5,058; copy number 7: 2,201; copy number 8: 345.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RL-01A-11D-A32M-01): tumor purity 0.59, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
